Somatic mutation profile of tumor specimen TCGA-EK-A2H1-01A (aliquot TCGA-EK-A2H1-01A-11D-A17W-09) from TCGA case TCGA-EK-A2H1, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 20.9 years (7,649 days).
Specimen TCGA-EK-A2H1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e21ff74b-39a3-467a-9537-996251654b3f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2H1-10A (Blood Derived Normal), aliquot TCGA-EK-A2H1-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/836ecc5e-2d06-46e8-bd72-c73ce60deb65

The open-access MAF lists 31 somatic variants for this specimen: 26 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Nonsense Mutation 4, Silent 3, RNA 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD50 | c.3446C>T p.S1149L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs1225400170, COSV72385307; called by muse, mutect2, varscan2
- BCAT2 | c.1149C>G p.I383M | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV60272106; called by muse, mutect2, varscan2
- BICRA | c.3361C>G p.Q1121E | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV67604235; called by muse, mutect2, varscan2
- CDX4 | c.437C>G p.A146G | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.381); catalogued as COSV65171525; called by muse, mutect2, varscan2
- CNBD1 | c.697C>T p.H233Y | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1403298132, COSV72976001; called by muse, mutect2, varscan2
- COG2 | c.1865A>T p.H622L | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.124); catalogued as COSV64186243; called by muse, mutect2, varscan2
- DMD | c.8579C>A p.P2860H | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0.045); catalogued as rs72466569, COSV100629115; called by muse, mutect2, varscan2
- DSCAML1 | c.2432C>T p.S811L (on ENST00000321322; = p.S751L on NM_020693.4) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58385668; called by muse, mutect2, varscan2
- FBXO4 | c.229C>T p.H77Y | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV55851663; called by muse, mutect2
- FPGT | c.1535C>T p.S512L | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as rs1482898286, COSV63836473; called by muse, mutect2, varscan2
- GCNT4 | c.1199G>A p.W400* | Nonsense Mutation (SNP) | VAF 8/63 reads (13%) | catalogued as COSV59280603; called by muse, mutect2, varscan2
- HERC2 | c.13988C>G p.S4663C | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV55314381; called by muse, mutect2, varscan2
- JHY | c.958C>T p.Q320* | Nonsense Mutation (SNP) | VAF 6/53 reads (11%) | catalogued as COSV57073707; called by muse, mutect2, varscan2
- MON2 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54804885; called by muse, mutect2, varscan2
- NBEAL2 | c.4138C>G p.L1380V | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs764151856, COSV52755629; called by muse, mutect2, varscan2
- NF2 | c.1393G>T p.E465* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as CM035747, COSV58521700, COSV58534064; called by muse, mutect2, varscan2
- NLRP1 | c.2375T>A p.V792D | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV52561485; called by muse, mutect2, varscan2
- OBSCN | c.10825G>A p.V3609M | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as rs374049885, COSV52789522; called by muse, mutect2, varscan2
- OTUD7B | c.682G>T p.E228* | Nonsense Mutation (SNP) | VAF 10/94 reads (11%) | catalogued as COSV100967764; called by muse, mutect2
- PCDH15 | c.5115G>C p.K1705N (on ENST00000644397 / NM_001354429.2; = p.K1647N on NM_001142771.2) | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.215); catalogued as COSV64679873, COSV64705417; called by muse, mutect2
- PLEKHG5 | c.1474G>A p.D492N (on ENST00000400915 / NM_001042663.3; = p.D455N on NM_020631.6) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.091); catalogued as rs1184812269, COSV61068012; called by muse, varscan2
- PRAG1 | c.3814G>A p.E1272K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs779317691, COSV100423010, COSV58159179; called by muse, mutect2, varscan2
- RBM3 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV63202385; called by muse, mutect2, varscan2
- SEC14L4 | c.1080C>G p.V360= | Splice Region (SNP) | VAF 25/68 reads (37%) | catalogued as COSV55398974; called by muse, mutect2, varscan2
- STS | c.599G>T p.C200F | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV99481625; called by muse, mutect2
- TCF20 | c.2113C>G p.L705V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV59489398; called by muse, mutect2, varscan2
- NCL | c.1560C>A p.G520= | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- TBC1D4 | c.1327C>T p.L443= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs778495732, COSV66488313; called by muse, mutect2, varscan2
- TPO | c.588G>A p.L196= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV61097802; called by muse, mutect2, varscan2
- MGAT5B | c.1025+7509G>A | Intron (SNP) | VAF 8/44 reads (18%) | catalogued as COSV56927120; called by muse, mutect2, varscan2
- SNORD115-36 | n.36G>A | RNA (SNP) | VAF 15/112 reads (13%) | called by muse, mutect2, varscan2
